Surgical pathology report (de-identified scan), TCGA case TCGA-AC-A62V, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-AC-A62V-01A (Primary Tumor).

[page 1 of 12]
Patient:

Referring Physician:

DOB

Age:

Gender: M

Ref#:

Hosp#:

Provider Group:

Date of Service:

Date Received:

Inpatient:

Case #

Date Reported:

ADDENDUM SURGICAL PATHOLOGY REPORT

Addendum Information:

This addendum report is issued to the provide results of breast carcinoma biomarker studies, performed on the previous ultrasound-guided core needle biopsy of the primary breast carcinoma () biomarker results:

Estrogen receptor: 100% positive cells, strong intensity.

Progesterone receptor: Less than 1% positive cells.

HER2: IHC score 0.

Ki-67 proliferative index: 35% positive cells.

The above results are similar to the those obtained on the metastatic carcinoma in the left iliac bone

Diagnosis:

A. LEFT BREAST, PROPHYLACTIC MASTECTOMY:

- Gynecomastia.
- Unremarkable skin and nipple.
- Negative for malignancy.

B. RIGHT BREAST, MODIFIED RADICAL MASTECTOMY:

- Invasive ductal carcinoma, Nottingham grade 3.
- Tumor size: 4.7 cm in diameter.
- Focal features of invasive micropapillary carcinoma.
- Ductal carcinoma in situ (DCIS), high nuclear grade.
- Cribriform and papillary architecture.
- Comedo necrosis and calcifications present.
- DCIS present adjacent to invasive carcinoma, in lactiferous ducts, and focally in upper inner quadrant.
- Mastectomy margins are free of tumor.
- Carcinoma is 0.2 cm from the deep margin, and is at least 2 cm from all other margins.
- Metastatic carcinoma in 3 of 17 axillary lymph nodes.

ICD-O-3 NOS
Carcinoma, infiltrating duct
Site (R) Breast NOS C50.9
path (R) Breast, upper-inner
quadrant C50.4
AS 5/10/13

Case #:

Page 1

Printed:

This report continues.

[page 2 of 12]
Patient:

Case #:

ADDENDUM SURGICAL PATHOLOGY REPORT

- No extranodal extension is identified.
- Largest metastatic focus measures 1.3 cm in diameter.
- Gynecomastia.

PATHOLOGIC TUMOR STAGING SYNOPSIS:

Type and grade (invasive): Invasive ductal carcinoma, Nottingham grade 3.

Primary tumor: pT2.

Regional lymph nodes: pN1a.

Distant metastasis: pM1 (metastasis to iliac bone).

Lymphovascular invasion: Present.

Pathologic stage: IV.

Margin status: Negative.

Invasive Breast Cancer Tumor Staging Information

AJCC Cancer Staging Handbook, 7th Ed., and CAP Protocol (revised June 2012).

Previous pathology specimens: (breast biopsy), left iliac bone biopsy).

Case #:

Printed:

Page 2

This report continues ...

[page 3 of 12]
Patient:

Case #:

SPECIMEN IDENTIFICATION

Procedure/specimen type:

Laterality:

Lymph node sampling:

Modified radical mastectomy.

Right.

Lymph node dissection.

INVASIVE CARCINOMA TUMOR CHARACTERISTICS

Histologic type:

Tumor site:

Tumor size:

Tumor focality:

Histologic grade (Nottingham Score):

Tubule formation:

Nuclear pleomorphism:

Mitotic rate:

Invasive ductal carcinoma.

Upper outer quadrant.

4.7 cm.

Single focus of invasive carcinoma.

3 of 3.

3 of 3.

3 of 3.

3 of 3.

Lymphovascular invasion:

Macroscopic and microscopic extent of tumor:

Present.

No skin or chest wall invasion identified.

DUCTAL CARCINOMA IN SITU (DCIS):

high nuclear grade

MARGINS

Invasive carcinoma:

0.2 cm from deep margin, at least 2 cm from all other margins.

Ductal carcinoma in situ:

at least 1 cm from all margins.

LYMPH NODES

Total lymph nodes examined

Number of lymph nodes involved

Size of largest metastatic deposit:

Extranodal extension:

17

3

1.3 cm.

Not identified.

PATHOLOGIC STAGING:

Primary Tumor (pT):

Regional lymph nodes (pN):

Distant metastasis (pM):

AJCC Stage:

pT2.

pN1a

pM1.

IV.

ANCILLARY STUDIES:

Estrogen receptor:

Progesterone receptor:

HER2:

Ki-67:

ProPath, : performed on bone biopsy

100% positive cells, strong intensity.

0% positive cells.

IHC score 1+.

15% positive cells.

Case #

Printed: ~

Page 3

This report continues.

[page 4 of 12]
Patient:

Case #:

ADDENDUM SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Breast:left complete mastectomy
- B. Breast:right modified radical mastectomy

Clinical History/Operative Dx:

None provided.

Gross Description:

A. The specimen is labeled left breast complete mastectomy and is received in formalin. It consists of a mastectomy specimen which weighs 227 grams. A black suture with a metallic clip marks the "tail of the breast". With this orientation the specimen measures 18.5 cm from medial to lateral, 11.8 cm from superior to inferior, and 2.5 cm superficial to deep. There is an overlying broad ellipse of dark brown skin which measures 17 x 6.5 cm. Centrally and slightly superiorly within the skin is a 2.3 cm areola and a protuberant 0.7 cm nipple. The anterior-superior margin is inked blue, the anterior-inferior margin is inked green, and the posterior margin, which consists of smooth fascial tissue, is inked black.

The specimen is serially sectioned at close intervals to reveal lobulated fatty tissue and centrally located tan-white fibrous parenchyma. There are no areas which have a stellate or retracted appearance suggestive of neoplasm. In the lateral portion of the specimen, 2 cm from the lateral edge, there is a circumscribed 0.7 cm pale red lymph node. Representative sections are submitted. Section summary:

- A1) nipple and tissue just deep to nipple,
- A2) representative upper inner quadrant,
- A3) representative lower inner quadrant,
- A4) representative upper outer quadrant,
- A5) representative lower outer quadrant,
- A6) representative central breast and representative central deep margin,
- A7) lateral lymph node.

Case #

Printed:

Page 4

This report continues.

[page 5 of 12]
Patient: [REDACTED]

Case #:

ADDENDUM SURGICAL PATHOLOGY REPORT

B. The specimen is labeled right breast modified radical mastectomy and is received without fixative. It consists of a mastectomy specimen together with axillary tissue weighing 292 grams. The breast measures 16 cm from medial to lateral, 9 cm from superior to inferior and up to 4 cm from superficial to deep. There is an overlying ellipse of dark brown skin which measures 15.5 x 7.6 cm. Slightly medially located within the skin is a circumscribed 2.5 cm areola and a protuberant 0.6 cm nipple. The skin is unremarkable. Axillary tissue is present and measures 15 x 6.5 x 1.8 cm. The anterior-superior margin is inked blue, the anterior-inferior margin is inked green, and the posterior margin, which consists of smooth facial tissue, is inked black. In the central lateral portion of the deep margin, there is a 3 x 0.5 cm band of skeletal muscle which is indicated by the surgeon as pectoralis major behind the tumor.

The specimen is serially sectioned at close intervals to reveal a relatively well-circumscribed, firm, tan-white tumor mass beginning directly underneath the nipple and extending laterally within the breast. This tumor mass measures 4.7 cm from medial to lateral, 4.5 cm from superior to inferior, and 3.5 cm from superficial to deep. This neoplasm is 3.5 cm from the closest medial margin, 5 cm from the axillary tail, 2.5 cm from the closest superior margin, and 2.2 cm from the closest inferior margin. Centrally, it is grossly 0.2 cm from the closest deep margin and does not appear to extend into the small strip of pectoralis muscle. The remainder of the breast is composed of soft fatty tissue without other palpable masses. Representative tumor and adjacent breast parenchyma are obtained for research purposes. In the medial portion of the axillary tail, there is a prominent firm 1.5 cm lymph node suspicious for metastatic involvement. Representative tissue from this lymph node is obtained for research purposes also. The axillary tissue is dissected for nodes. Representative sections are submitted.

Section summary:

- B1) nipple and tissue just deep to nipple,
- B2) representative lateral skin overlying tumor,
- B3) medial edge of tumor,
- B4-B11) sections of tumor progressing from medial to lateral,
- B12) section of tumor and closest approach to deep margin,
- B13) deep margin with pectoralis muscle,
- B14) representative upper inner quadrant,
- B15) representative lower inner quadrant,
- B16) representative upper outer quadrant,
- B17) representative lower outer quadrant,
- B18) medial axillary node (some submitted for research),
- B19) single node, multiply sectioned,
- B20) single node, multiply sectioned,
- B21) one larger node, serially sectioned, two smaller nodes inked and bivalved,
- B22) two nodes, serially sectioned (one inked),
- B23-B24) smaller possible nodes, intact. [REDACTED]

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis

Case #

Page 5

Printed:

This report continues...

[page 6 of 12]
Patient:

Case #:

ADDENDUM SURGICAL PATHOLOGY REPORT

rendered.

Final report originally signed by

Case #

Printed:

Page 6

END OF REPORT (ADDENDUM)

[page 7 of 12]
Patient:

Referring Physician:

DOB: Age: Gender: M

Ref#: Hosp#: Provider Group:

Date of Service: Date Received: Inpatient Case #
Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. LEFT BREAST, PROPHYLACTIC MASTECTOMY:

- Gynecomastia.
- Unremarkable skin and nipple.
- Negative for malignancy.

B. RIGHT BREAST, MODIFIED RADICAL MASTECTOMY:

- Invasive ductal carcinoma, Nottingham grade 3.
- Tumor size: 4.7 cm in diameter.
- Focal features of invasive micropapillary carcinoma.
- Ductal carcinoma in situ (DCIS), high nuclear grade.
- Cribriform and papillary architecture.
- Comedo necrosis and calcifications present.
- DCIS present adjacent to invasive carcinoma, in lactiferous ducts, and focally in upper inner quadrant.
- Mastectomy margins are free of tumor.
- Carcinoma is 0.2 cm from the deep margin, and is at least 2 cm from all other margins.
- Metastatic carcinoma in 3 of 17 axillary lymph nodes.
- No extranodal extension is identified.
- Largest metastatic focus measures 1.3 cm in diameter.
- Gynecomastia.

PATHOLOGIC TUMOR STAGING SYNOPSIS:

Type and grade (invasive): Invasive ductal carcinoma, Nottingham grade 3.
Primary tumor: pT2.
Regional lymph nodes: pN1a.
Distant metastasis: pM1 (metastasis to iliac bone).
Lymphovascular invasion: Present.
Pathologic stage: IV.
Margin status: Negative.

Case #:

Printed:

Page 1

This report continues. (J. HALL)

[page 8 of 12]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Invasive Breast Cancer Tumor Staging Information

AJCC Cancer Staging Handbook, 7th Ed., and CAP Protocol (revised June 2012).

Previous pathology specimens: 1 (breast biopsy), (left iliac bone biopsy).

Case #:

Printed:

Page 2

This report continues (FINAL)

[page 9 of 12]
Patient:

Case #:

SPECIMEN IDENTIFICATION

Procedure/specimen type:

Laterality:

Lymph node sampling:

Modified radical mastectomy.

Right.

Lymph node dissection.

INVASIVE CARCINOMA TUMOR CHARACTERISTICS

Histologic type:

Tumor site:

Tumor size:

Tumor focality:

Histologic grade (Nottingham Score):

Tubule formation:

Nuclear pleomorphism:

Mitotic rate:

Invasive ductal carcinoma.

Upper outer quadrant.

4.7 cm.

Single focus of invasive carcinoma.

3 of 3.

3 of 3.

3 of 3.

3 of 3.

Lymphovascular invasion:

Macroscopic and microscopic extent of tumor:

Present.

No skin or chest wall invasion identified.

DUCTAL CARCINOMA IN SITU (DCIS):

high nuclear grade

MARGINS

Invasive carcinoma:

0.2 cm from deep margin, at least 2 cm from all other margins.

Ductal carcinoma in situ:

at least 1 cm from all margins.

LYMPH NODES

Total lymph nodes examined

Number of lymph nodes involved

Size of largest metastatic deposit.

Extranodal extension:

17

3

1.3 cm.

Not identified.

PATHOLOGIC STAGING:

Primary Tumor (pT):

Regional lymph nodes (pN):

Distant metastasis (pM):

AJCC Stage:

pT2.

pN1a

pM1.

IV.

ANCILLARY STUDIES:

Estrogen receptor:

Progesterone receptor:

HER2:

Ki-67:

ProPath, , performed on bone biopsy).

100% positive cells, strong intensity.

0% positive cells.

IHC score 1+.

15% positive cells.

Case #

Printed:

Page 3

This report continues... (FINAL)

[page 10 of 12]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Signed by:

Source of Specimen:

- A. Breast; left complete mastectomy
- B. Breast; right modified radical mastectomy

Clinical History/Operative Dx:

None provided.

Gross Description:

A. The specimen is labeled left breast complete mastectomy and is received in formalin. It consists of a mastectomy specimen which weighs 227 grams. A black suture with a metallic clip marks the "tail of the breast". With this orientation the specimen measures 18.5 cm from medial to lateral, 11.8 cm from superior to inferior, and 2.5 cm superficial to deep. There is an overlying broad ellipse of dark brown skin which measures 17 x 6.5 cm. Centrally and slightly superiorly within the skin is a 2.3 cm areola and a protuberant 0.7 cm nipple. The anterior-superior margin is inked blue, the anterior-inferior margin is inked green, and the posterior margin, which consists of smooth fascial tissue, is inked black.

The specimen is serially sectioned at close intervals to reveal lobulated fatty tissue and centrally located tan-white fibrous parenchyma. There are no areas which have a stellate or retracted appearance suggestive of neoplasm. In the lateral portion of the specimen, 2 cm from the lateral edge, there is a circumscribed 0.7 cm pale red lymph node. Representative sections are submitted. Section summary:

- A1) nipple and tissue just deep to nipple,
- A2) representative upper inner quadrant,
- A3) representative lower inner quadrant,
- A4) representative upper outer quadrant,
- A5) representative lower outer quadrant,
- A6) representative central breast and representative central deep margin,
- A7) lateral lymph node.

Case #

Printed:

Page 4

This report continues. (FINAL)

[page 11 of 12]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

B. The specimen is labeled right breast modified radical mastectomy and is received without fixative. It consists of a mastectomy specimen together with axillary tissue weighing 292 grams. The breast measures 16 cm from medial to lateral, 9 cm from superior to inferior and up to 4 cm from superficial to deep. There is an overlying ellipse of dark brown skin which measures 15.5 x 7.6 cm. Slightly medially located within the skin is a circumscribed 2.5 cm areola and a protuberant 0.6 cm nipple. The skin is unremarkable. Axillary tissue is present and measures 15 x 6.5 x 1.8 cm. The anterior-superior margin is inked blue, the anterior-inferior margin is inked green, and the posterior margin, which consists of smooth facial tissue, is inked black. In the central lateral portion of the deep margin, there is a 3 x 0.5 cm band of skeletal muscle which is indicated by the surgeon as pectoralis major behind the tumor.

The specimen is serially sectioned at close intervals to reveal a relatively well-circumscribed, firm, tan-white tumor mass beginning directly underneath the nipple and extending laterally within the breast. This tumor mass measures 4.7 cm from medial to lateral, 4.5 cm from superior to inferior, and 3.5 cm from superficial to deep. This neoplasm is 3.5 cm from the closest medial margin, 5 cm from the axillary tail, 2.5 cm from the closest superior margin, and 2.2 cm from the closest inferior margin. Centrally, it is grossly 0.2 cm from the closest deep margin and does not appear to extend into the small strip of pectoralis muscle. The remainder of the breast is composed of soft fatty tissue without other palpable masses. Representative tumor and adjacent breast parenchyma are obtained for research purposes. In the medial portion of the axillary tail, there is a prominent firm 1.5 cm lymph node suspicious for metastatic involvement. Representative tissue from this lymph node is obtained for research purposes also. The axillary tissue is dissected for nodes. Representative sections are submitted.

Section summary:

- B1) nipple and tissue just deep to nipple,
- B2) representative lateral skin overlying tumor,
- B3) medial edge of tumor,
- B4-B11) sections of tumor progressing from medial to lateral,
- B12) section of tumor and closest approach to deep margin,
- B13) deep margin with pectoralis muscle,
- B14) representative upper inner quadrant,
- B15) representative lower inner quadrant,
- B16) representative upper outer quadrant,
- B17) representative lower outer quadrant,
- B18) medial axillary node (some submitted for research),
- B19) single node, multiply sectioned,
- B20) single node, multiply sectioned,
- B21) one larger node, serially sectioned, two smaller nodes inked and bivalved,
- B22) two nodes, serially sectioned (one inked),
- B23-B24) smaller possible nodes, intact.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis

Case #:

Printed:

Page 5

This report continues. (FINAL)

[page 12 of 12]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

rendered.

H/PA Discrepancy		☒

Case #

Printed:

Page 6

END OF REPORT (FINAL)

Source: NCI Genomic Data Commons file 394db5c7-b1b0-478e-80dd-d640eb37e468 (TCGA-AC-A62V.BBA96852-E70C-4D37-A185-611F568BE90C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).